Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A16D, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A16D-01A (Primary Tumor).

1CD-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Site Code: Endometrium C54.1

Surgical Pathology

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 A8 A9 A10 B1

Uterus, right ovary (2.2 x 1.4 x 0.8 cm) with 8.2 cm segment of right fallopian tube, and left ovary (2.4 x 1.4 x 1.1 cm) with 7.4 cm segment of left fallopian tube together weighing 145.0 grams and separately submitted appendix (5.1 x 0.3 cm).

DIAGNOSIS:

Uterus, hysterectomy: FIGO grade I (of III) endometrial adenocarcinoma, endometrioid type, is identified arising in a

background of polypoid atypical hyperplasia. (2.8 x 2.4 x 0.8 cm).

The adenocarcinoma (1.2 cm in greatest linear extent) is limited to

the endometrium with no myometrial invasion. There is no lymph-vascular space involvement. The endocervix is uninvolved.

The myometrium shows superficial adenomyosis. The cervix is unremarkable.

Ovaries, left and right, oophorectomy: Atrophic ovary, otherwise unremarkable, bilaterally.

Fallopian tubes, left and right, salpingectomy: Unremarkable.

Appendix, appendectomy: Unremarkable.

Source: NCI Genomic Data Commons file 0454acdf-3169-43ba-aa10-a58703ec193a (TCGA-D1-A16D.795A5264-493A-498D-A731-87ECB0A7F612.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).